Somatic mutation profile of tumor specimen TARGET-20-PARCUK-09A (aliquot TARGET-20-PARCUK-09A-01D) from TARGET case TARGET-20-PARCUK, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.4 years (5,987 days).
Specimen TARGET-20-PARCUK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10fcdca2-2673-433f-a5a8-1ecb11c74754.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARCUK-14A (Bone Marrow Normal), aliquot TARGET-20-PARCUK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f1ef95e-ea12-43cf-b1e4-d1a0526ee478

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EOMES | c.1908C>T p.Y636= | Silent (SNP) | VAF 93/203 reads (46%) | catalogued as COSV55415830; called by muse, mutect2, varscan2
